Somatic mutation profile of tumor specimen TARGET-20-PARMZF-09A (aliquot TARGET-20-PARMZF-09A-02D) from TARGET case TARGET-20-PARMZF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,163 days).
Specimen TARGET-20-PARMZF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0c6c4fe-1343-4192-8459-8ae0478385c2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARMZF-14A (Bone Marrow Normal), aliquot TARGET-20-PARMZF-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f766e93d-eafc-418e-8735-5206cc6b2bea

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1248_1259delinsCCTGGC p.T417_R420delinsLA | In Frame Del (DEL) | VAF 77/248 reads (31%) | called by pindel, varscan2*
- SIX1 | c.*1080_*1081insT | 3'UTR (INS) | VAF 57/156 reads (37%) | called by mutect2, varscan2
